Gene-level copy-number profile of tumor specimen TCGA-A5-A2K2-01A from TCGA case TCGA-A5-A2K2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 77.9 years (28,456 days).
Specimen TCGA-A5-A2K2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.6b1acda5-81bd-4e5f-afc6-0be0707cf8d1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A5-A2K2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/25718f16-9f63-427d-9ff3-97433687a7f9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,396; copy number 3: 20,646; copy number 4: 25,750; copy number 5: 6,376; copy number 6: 1,275; copy number 7: 231; copy number 8: 908; copy number 9: 127; copy number 10: 24; copy number 11: 36; copy number 12: 24; copy number 13: 11; copy number 14: 3; copy number 20: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A5-A2K2-01A-11D-A18N-01): tumor purity 0.81, ploidy 3.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 235 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:33,162,179–36,347,157, 56 genes, copy number 9–20: AC010343.1, LINC02160, AC025472.1, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138409.3, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1.
- chr6:11,173,452–11,709,960, 11 genes, copy number 13 (within-gene range 6–13): AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1.
- chr7:55,019,017–55,260,256, 5 genes, copy number 9: EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr8:43,672,823–43,674,591, 2 genes, copy number 10: AC139365.2, AC139365.1.
- chr8:125,859,721–126,292,788, 1 gene, copy number 11 (within-gene range 6–11): LINC00861.
- chr8:125,998,994–128,564,679, 40 genes, copy number 9–14 (within-gene range 6–14): AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr14:24,809,656–26,143,305, 11 genes, copy number 9–10 (within-gene range 5–10): STXBP6, AL161663.2, AL161663.1, LINC02286, HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1.
- chr14:34,561,093–36,068,261, 44 genes, copy number 9 (within-gene range 5–9): SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1.
- chr17:9,822,206–10,623,886, 14 genes, copy number 11 (within-gene range 5–11): GLP2R, NPM1P45, RCVRN, GAS7, RPS27AP1, AC005291.2, MYH13, AC005291.1, AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2.
- chr19:27,638,483–29,015,160, 34 genes, copy number 9: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532.
- chr20:37,178,410–37,872,129, 15 genes, copy number 10 (within-gene range 6–10): RPN2, GHRH, MANBAL, AL034422.1, SRC, RPL7AP14, BLCAP, NNAT, AL109614.1, PPIAP3, LINC01746, GLRXP1, LINC00489, AL162293.1, CTNNBL1.
- chr20:54,859,688–55,075,140, 2 genes, copy number 10: RNU4ATAC7P, RPL12P4.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
